Somatic mutation profile of tumor specimen 0DHOJ7 from CCDI case PBBUTM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,422 days).
Specimen 0DHOJ7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4433cdd-e098-490c-a7b9-172a751018cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHOGV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bb78c9b-6d17-446b-a4cf-5516d40fa345

The open-access MAF lists 30 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 11, Missense Mutation 9, Silent 3, Nonsense Mutation 3, 5'UTR 1, 3'UTR 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 137/504 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 238/731 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4600C>T p.R1534* (on ENST00000358273 / NM_001042492.3; = p.R1513* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 140/640 reads (22%) | catalogued as rs760703505, CM941093, COSV62191852; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- NF1 | c.5610-2A>G p.X1870_splice (on ENST00000358273 / NM_001042492.3; = p.X1849_splice on NM_000267.3) | Splice Site (SNP) | VAF 134/419 reads (32%) | catalogued as rs1135402876, CS153443, CS165117; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.5167C>T p.R1723* | Nonsense Mutation (SNP) | VAF 94/1265 reads (7%) | catalogued as rs121918267, CM042514, COSV56952714; ClinVar: pathogenic; called by muse, mutect2
- ARFGEF2 | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 170/684 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs752285808; called by muse, mutect2, varscan2
- BOD1L1 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 104/1392 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs745506657; called by muse, mutect2
- NEK1 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 308/1190 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.058); catalogued as rs376649040; called by muse, varscan2
- PSG2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 197/720 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs777210176, COSV61545245; called by muse, mutect2, varscan2
- ALK | c.2267G>A p.G756D | Missense Mutation (SNP) | VAF 235/822 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MXRA5 | c.5106T>G p.F1702L | Missense Mutation (SNP) | VAF 223/817 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- POM121L2 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 71/836 reads (8%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.903); called by muse, mutect2
- PPP4R3C | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 80/831 reads (10%) | called by muse, mutect2
- C1QL1 | c.678C>T p.A226= | Silent (SNP) | VAF 36/1134 reads (3%) | called by muse, mutect2
- WDFY3 | c.4897T>C p.L1633= | Silent (SNP) | VAF 81/1152 reads (7%) | catalogued as rs1245716162; called by muse, mutect2
- ZBTB37 | c.1212C>T p.R404= | Silent (SNP) | VAF 30/718 reads (4%) | catalogued as rs1450054540; called by muse, mutect2
- ADRA2B | c.-50C>T | 5'UTR (SNP) | VAF 16/54 reads (30%) | catalogued as rs1192498273; called by muse, mutect2, varscan2
- CEP112 | c.2697+92T>C | Intron (SNP) | VAF 30/372 reads (8%) | called by muse, mutect2
- CHD1L | c.1270+94C>T | Intron (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- DENND2C | c.2755+70T>C | Intron (SNP) | VAF 30/345 reads (9%) | called by muse, mutect2
- GJD4 | c.*48A>G | 3'UTR (SNP) | VAF 40/302 reads (13%) | called by muse, varscan2
- MCM3AP | c.4647+85G>A | Intron (SNP) | VAF 81/272 reads (30%) | catalogued as rs1006518841; called by muse, mutect2, varscan2
- MIR9-1HG | n.575-91T>C | Intron (SNP) | VAF 25/201 reads (12%) | called by muse, varscan2
- NLN | c.559-90T>G | Intron (SNP) | VAF 24/174 reads (14%) | called by muse, varscan2
- OR7G2 | chr19:9102180 A>T | 3'Flank (SNP) | VAF 10/78 reads (13%) | called by muse, varscan2
- PCSK6 | c.2813-85G>C | Intron (SNP) | VAF 12/104 reads (12%) | called by muse, varscan2
- PNO1 | c.621-73T>C | Intron (SNP) | VAF 44/341 reads (13%) | catalogued as COSV55152537; called by muse, mutect2
- PRR11 | c.1014+80T>C | Intron (SNP) | VAF 41/437 reads (9%) | called by muse, mutect2
- RAB13 | c.325-85T>C | Intron (SNP) | VAF 19/203 reads (9%) | called by muse, mutect2
- SLC50A1 | c.158+118T>A | Intron (SNP) | VAF 15/112 reads (13%) | catalogued as rs1014170885; called by muse, mutect2
